Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19K, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19K-01A (Primary Tumor).

1CB-0-3

Melanoma, NOS 8720/3

12/15/10 lw

Site Code: Scalp, skin C44.4

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Scalp melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Wide excision melanoma, says biopsy, skin graft

FINAL DIAGNOSIS:

PART 1: SKIN, LEFT SCALP, WIDE EXCISION OF MELANOMA SITE -

- A. MALIGNANT MELANOMA, FOCALLY ULCERATED. LEVEL V; 6.8 MM (see comment).
- B. MULTIPLE FOCI OF ANGIOLYMPHATIC INVASION PRESENT.
- C. MULTIPLE FOCI OF CUTANEOUS AND DERMAL SATELLITES PRESENT.
- D. RESECTION MARGINS, INCLUDING DEEP MARGIN, ARE FREE OF TUMOR (see comment).

PART 2: LYMPH NODE, LEFT SENTINEL #1, EXCISION -

- A. FIBROUS TISSUE AND SKELETAL MUSCLE.
- B. NO LYMPH NODE SEEN.

PART 3: LYMPH NODE, LEFT SENTINEL #2, EXCISION -

FIBROMUSCULAR SOFT TISSUE AND NERVE, FREE OF TUMOR.

COMMENT:

PART:1 : REF: 8720/3

PARTS 2&3 : NO tumor cells nor lymph nodes seen on routine stains or the immunostains for s100, Melan a, HMB45, tyrosinase or CD68.

HIF-AA Discrepancy		X

Source: NCI Genomic Data Commons file d02f566d-ed52-4a5d-9af0-0a3b1a0b1ee6 (TCGA-ER-A19K.8EE44608-F186-46BB-ADA5-88888ED75A15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).